FM case AD15325 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/90f101a2-4f92-457b-aa65-6c669e67b957

Female, 37.1 years: Solid pseudopapillary tumor (ICD-O-3 8452/1) of the pancreas; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 23% (pathologist estimate recorded by GDC). Sample type: Metastatic.
